Somatic mutation profile of tumor specimen TARGET-10-PATGMP-09A (aliquot TARGET-10-PATGMP-09A-01D) from TARGET case TARGET-10-PATGMP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.7 years (3,924 days).
Specimen TARGET-10-PATGMP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47a4d290-31fa-4747-a574-6193e68b6d11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATGMP-10A (Blood Derived Normal), aliquot TARGET-10-PATGMP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae223bfc-c07a-4251-b748-d589067a3815

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Nonsense Mutation 4, Silent 2, 3'UTR 2, Splice Site 1, Intron 1, 5'Flank 1, 5'UTR 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 41/89 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PHF6 | c.673C>T p.R225* (on ENST00000332070 / NM_032458.3; = p.R226* on NM_032335.3) | Nonsense Mutation (SNP) | VAF 33/37 reads (89%) | catalogued as rs1556018932, COSV59699600; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 62/151 reads (41%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 37/106 reads (35%) | hotspot (GDC flag); catalogued as rs121909231, CM971278, COSV64288687, COSV64297951; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGRN | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs772421157, COSV65072496; called by muse, mutect2, varscan2
- AOPEP | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1027115168, COSV52917346; called by muse, mutect2, varscan2
- APOB | c.13348G>A p.E4450K | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.163); catalogued as rs866063436, COSV51953846; called by muse, mutect2
- CD2AP | c.661A>G p.K221E | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV63763219; called by muse, mutect2, varscan2
- COL26A1 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747060134, COSV58133035; called by muse, mutect2, varscan2
- DIP2B | c.679T>C p.S227P | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV56592674; called by muse, mutect2, varscan2
- KCNAB3 | c.721T>A p.S241T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.084); catalogued as COSV58141617; called by muse, mutect2, varscan2
- MAGI1 | c.960-2A>G p.X320_splice | Splice Site (SNP) | VAF 15/37 reads (41%) | catalogued as COSV58345946; called by muse, mutect2, varscan2
- PITPNM1 | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763245484, COSV56874631; called by muse, mutect2, varscan2
- RCOR2 | c.339G>A p.W113* | Nonsense Mutation (SNP) | VAF 4/72 reads (6%) | catalogued as COSV56849411; called by muse, mutect2
- BCL11B | c.100_101insGGCTAATTCG p.E34Gfs*24 | Frame Shift Ins (INS) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- CRYBG3 | c.1956C>A p.F652L | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRAJ47 | c.2_6del p.E2Wfs*? | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- CNGA4 | c.954C>T p.N318= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs375543350, COSV66007053; called by muse, mutect2, varscan2
- SLC4A3 | c.2928C>A p.G976= | Silent (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- CDKN2B | c.*114T>C | 3'UTR (SNP) | VAF 8/10 reads (80%) | called by muse, mutect2, varscan2
- KCP | chr7:128913171 G>A | 5'Flank (SNP) | VAF 9/26 reads (35%) | catalogued as rs1188307118; called by muse, mutect2, varscan2
- SCGB1A1 | c.-39C>T | 5'UTR (SNP) | VAF 21/83 reads (25%) | catalogued as rs748127430; called by muse, mutect2, varscan2
- SLC25A27 | c.299-83G>A | Intron (SNP) | VAF 30/67 reads (45%) | catalogued as rs200498534; called by muse, mutect2, varscan2
- TMEM63B | c.*13G>A | 3'UTR (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
